Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3CP, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3CP-01A (Primary Tumor).

HUPAA Discrepancy	☒	☒

10/15/11

ry Case gy Report Pathology,

DOB:
Physician.

Sex: F

Received:

Pathologist: :

Accession:

Case type: Surgical History

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to the section "SPECIMEN" may have been added. ****

DIAGNOSIS

(A) PARATHYROID, RIGHT INFERIOR, BIOPSY:
Parathyroid tissue.

(B) THYROID, TOTAL THYROIDECTOMY:
PAPILLARY CARCINOMA OF THYROID, FOLLICULAR VARIANT (1.1 CM) INVOLVING
SUPERIOR RIGHT LOBE.
TUMOR EXTENDS TO SURGICAL MARGIN. (SEE COMMENT)
No lymphatic invasion identified.

10B-0-3

carcinoma, papillary, follicular
variant
Site: thyroid, NOS C73.9 8340/3

Entire report and diagnosis completed by:
Report released by:

hw 10/15/11

COMMENT:

The tumor in the superior aspect of the right lobe appears well-circumscribed but extends to the surgical margin. Adjacent soft tissue is not present to evaluate the possibility of extension beyond the thyroid.

GROSS DESCRIPTION:

(A) CONFIRM RIGHT PARATHYROID INFERIOR - Three soft pink-tan fragments (in aggregate 0.4 x 0.3 x 0.1 cm). In toto, frozen section.

*FS/DX: PARATHYROID TISSUE.

(B) TOTAL THYROID - A complete thyroid gland which does not appear enlarged. A well-circumscribed 1.1 cm mass is present in the superior aspect of the right lobe. The mass grossly extends to the surface of the specimen. Sectioning reveals the mass to exhibit a solid tan cut surface. The remaining thyroid tissue is grossly unremarkable.

SECTION CODE: B1-B7, B1-B11, grossly unremarkable sections from right and left lobes of thyroid; B8-B9, tumor from superior right lobe.

SNOMED CODES

Source: NCI Genomic Data Commons file 7e40f446-9882-4b45-a1fd-22231591d22b (TCGA-EL-A3CP.23E47F7A-AD84-45A5-B959-2E2290457BD3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).